Gene-level copy-number profile of tumor specimen MP2PRT-PARLMM-TMP1-A from MP2PRT case MP2PRT-PARLMM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,297 days).
Specimen MP2PRT-PARLMM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d3c3f3c-8c0f-4691-bd8d-b2e6d4dcb62d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARLMM-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/163128c3-77cb-40bc-bb89-edec7f152daa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 224; copy number 1: 152; copy number 2: 57,994; copy number 3: 22.

Homozygous deletions (total copy number 0; autosomes only): 224 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,159,751–89,192,752, 5 genes (within-gene range 0–1): IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr2:89,985,922–90,047,057, 8 genes: IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19.
- chr7:142,670,740–142,802,748, 28 genes (within-gene range 0–2): TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr14:22,449,113–22,459,156, 5 genes (within-gene range 0–2): TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:22,483,004–22,511,024, 23 genes (within-gene range 0–2): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31.
- chr14:105,672,308–106,631,653, 150 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,637,718–106,639,657, 2 genes (within-gene range 0–2): IGHVII-60-1, IGHV4-61.
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–2): IGHV3-64, IGHV3-65, IGHVII-65-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
